Somatic mutation profile of tumor specimen ER-ACGR-TTP1-A (aliquot ER-ACGR-TTP1-A-1-0-D-A49L-35) from EXCEPTIONAL_RESPONDERS case ER-ACGR, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 52.1 years (19,015 days).
Specimen ER-ACGR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0091a6ce-e46b-41fc-9678-33ff6826f159.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-ACGR-NB1-A (Blood Derived Normal), aliquot ER-ACGR-NB1-A-1-0-D-A49L-35; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2aa9b53-cef3-4abb-87ca-ba8a7f79b15a

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 43/247 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ROS1 | c.4375G>T p.A1459S | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV63852809; called by muse, mutect2
- SRC | c.739G>C p.V247L | Missense Mutation (SNP) | VAF 14/219 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV62440259; called by muse, mutect2
